Somatic mutation profile of tumor specimen 0DPYE3 from CCDI case PBCDWG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 8.0 years (2,906 days).
Specimen 0DPYE3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc80ada-fb11-4d6b-9f45-328c0303808b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPYD6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7f59a49-5c1a-44ad-bce3-b2c3653873b5

The open-access MAF lists 27 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 5, Silent 3, Splice Site 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B2 | c.3187G>T p.A1063S (on ENST00000261722; = p.A1057S on NM_004644.5) | Missense Mutation (SNP) | VAF 271/543 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.463); catalogued as COSV55613331; called by muse, mutect2, varscan2
- ATP2C2 | c.919G>A p.G307S | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs770472116, COSV52298724; called by muse, mutect2, varscan2
- EVI5L | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 73/519 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1030298860, COSV54484522; called by muse, mutect2, varscan2
- GPHB5 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 236/462 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs759641700, COSV58485790; called by muse, mutect2, varscan2
- HNRNPDL | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1210768968; called by muse, mutect2
- KBTBD4 | c.888_889insGGG p.R296_R297insG | In Frame Ins (INS) | VAF 176/390 reads (45%) | catalogued as COSV58597484; called by mutect2, pindel, varscan2
- MBD1 | c.1040G>A p.R347Q (on ENST00000269468 / NM_001323950.1; = p.R324Q on NM_015845.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/618 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as rs1414852111, COSV54004010; called by muse, mutect2, varscan2
- RFT1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV56250547; called by muse, mutect2
- STARD10 | c.866C>T p.S289L | Missense Mutation (SNP) | VAF 121/393 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as rs1375650745, COSV58324962; called by muse, mutect2, varscan2
- TSKS | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 129/290 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754948650; called by muse, mutect2, varscan2
- ALPK3 | c.3479C>G p.A1160G | Missense Mutation (SNP) | VAF 34/265 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AUTS2 | c.2309C>T p.T770I | Missense Mutation (SNP) | VAF 240/372 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- C6orf52 | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 148/451 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PRDM8 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 224/469 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- STRN3 | c.1524C>A p.N508K (on ENST00000357479 / NM_001083893.2; = p.N424K on NM_014574.4) | Missense Mutation (SNP) | VAF 190/633 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SVEP1 | c.3484+2_3484+5del p.X1162_splice | Splice Site (DEL) | VAF 189/373 reads (51%) | called by mutect2, pindel, varscan2
- XIRP2 | c.194C>T p.A65V (on ENST00000628543; = p.A240V on NM_152381.6) | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF704 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 106/416 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PAAF1 | c.504C>T p.C168= | Silent (SNP) | VAF 252/552 reads (46%) | catalogued as rs762334840, COSV100142421; called by muse, mutect2, varscan2
- PRAMEF20 | c.1416G>A p.R472= | Silent (SNP) | VAF 14/428 reads (3%) | called by muse, mutect2
- TRPM3 | c.4188T>C p.D1396= (on ENST00000357533 / NM_001366142.2; = p.D1251= on NM_020952.6) | Silent (SNP) | VAF 20/567 reads (4%) | called by muse, mutect2
- AP003393.1 | n.515-716G>A | Intron (SNP) | VAF 188/404 reads (47%) | catalogued as rs138658500; ClinVar: likely benign; called by muse, mutect2, varscan2
- AP3D1 | c.2602-1140G>A | Intron (SNP) | VAF 159/639 reads (25%) | catalogued as rs763277675, COSV100643116; called by muse, mutect2, varscan2
- FOXP2 | c.1094+31C>T | Intron (SNP) | VAF 208/788 reads (26%) | catalogued as rs763921047; called by muse, mutect2, varscan2
- NDUFS7 | c.544+9G>A | Intron (SNP) | VAF 124/276 reads (45%) | catalogued as rs756896939; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOSIP | c.538-57C>T | Intron (SNP) | VAF 93/153 reads (61%) | called by muse, mutect2, varscan2
- PRKCH | c.*35C>T | 3'UTR (SNP) | VAF 27/276 reads (10%) | called by muse, mutect2
